Somatic mutation profile of tumor specimen 0DWTBP from CCDI case PBCPHM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myofibroblastic tumor, NOS; Tissue or organ of origin: Mandible; Age at diagnosis: 14.7 years (5,379 days).
Specimen 0DWTBP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c40f484-d512-4751-a0c2-d33b8e5b4941.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWTAB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c74a48d1-3213-428f-b748-65c7d1f5394d

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42BPA | c.4131G>T p.Q1377H (on ENST00000334218 / NM_001366019.2; = p.Q1364H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/311 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CEP120 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 28/768 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- DCPS | c.540C>T p.L180= | Silent (SNP) | VAF 98/437 reads (22%) | catalogued as rs769192861, COSV55011647; called by muse, mutect2, varscan2
- MKS1 | c.644+78C>T | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, varscan2
